Somatic mutation profile of tumor specimen MMRF_2816_1_BM_CD138pos (aliquot MMRF_2816_1_BM_CD138pos_T1_KHS5U_L15702) from MMRF case MMRF_2816, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,057 days).
Specimen MMRF_2816_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fbc486f-9203-4b17-8f1f-027dc4dd7e3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2816_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2816_1_PB_WBC_C3_KHS5U_L15748; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97c88d7b-3f94-4f62-81dc-e894e46b1d6e

The open-access MAF lists 153 somatic variants for this specimen: 68 protein-altering or splice-affecting, 21 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 39, Silent 21, Intron 14, 3'Flank 5, Nonsense Mutation 5, 5'UTR 5, Frame Shift Ins 2, Splice Site 2, Splice Region 2, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHS2 | c.467dup p.L156Ffs*11 | Frame Shift Ins (INS) | VAF 26/148 reads (18%) | catalogued as rs528833893; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 54/472 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10203C>T p.Y3401= | Splice Region (SNP) | VAF 34/230 reads (15%) | catalogued as rs1044000165; called by muse, varscan2
- AHR | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.662); catalogued as rs1447260865; called by muse, mutect2, varscan2
- ARFGEF3 | c.4345G>A p.G1449S | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539374966; called by muse, mutect2
- BID | c.685C>T p.R229C (on ENST00000317361 / NM_197966.2; = p.R183C on NM_001196.4) | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs538615870; called by muse, mutect2, varscan2
- BPTF | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 44/339 reads (13%) | catalogued as COSV100075392; called by muse, mutect2, varscan2
- C3 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778093127, COSV55572745; called by muse, mutect2, varscan2
- CASZ1 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1304236155, COSV59735514; called by muse, mutect2, varscan2
- CERS6 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59832857; called by muse, mutect2, varscan2
- CHD8 | c.6355A>C p.S2119R (on ENST00000646647 / NM_001170629.2; = p.S1840R on NM_020920.4) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV63036751; called by muse, mutect2, varscan2
- CNIH1 | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1236062802; called by muse, mutect2, varscan2
- CYFIP1 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as rs564838879; called by muse, mutect2, varscan2
- FOXD3 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs557946909; called by muse, mutect2, varscan2
- GSDMA | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs373240051; called by muse, mutect2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs754199513; called by mutect2, varscan2
- IGLV3-1 | c.280A>C p.S94R | Missense Mutation (SNP) | VAF 108/116 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs568311535; called by muse, varscan2
- LAMB4 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99223555; called by muse, mutect2, varscan2
- MPPED2 | c.841A>T p.N281Y | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63900168; called by muse, mutect2, varscan2
- MUC16 | c.2134C>A p.P712T | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1308501323, COSV101202180; called by muse, mutect2
- OCRL | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1437975458, COSV63981501; called by muse, mutect2, varscan2
- OR10W1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 126/195 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV67720295; called by muse, mutect2, varscan2
- PLB1 | c.4081G>A p.A1361T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749695328, COSV59832429; called by muse, mutect2, varscan2
- RB1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as CD071388; called by muse, mutect2, varscan2
- TBC1D2 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100579816; called by muse, mutect2, varscan2
- TEDC1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.235); catalogued as rs1172327769; called by muse, mutect2, varscan2
- ZIC2 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV66254554; called by muse, mutect2
- ZNF595 | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs548894326; called by muse, mutect2
- API5 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- ASCC3 | c.3172A>G p.N1058D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATR | c.1541+1G>A p.X514_splice | Splice Site (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- CDH19 | c.2293G>T p.G765C | Missense Mutation (SNP) | VAF 89/328 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CNTNAP1 | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 177/301 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COASY | c.701-3C>T | Splice Region (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- DUS3L | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- FZD8 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GORAB | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.089); called by muse, mutect2
- GSTA2 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- GYS2 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- H2AC16 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- IGHV2-70D | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, varscan2
- INO80 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IPO7 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- KCNU1 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- LINGO3 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 74/345 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MARCHF7 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFASC | c.2090A>T p.N697I (on ENST00000339876 / NM_001378329.1; = p.N693I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.318+2T>C p.X106_splice | Splice Site (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- OBSCN | c.21364C>T p.Q7122* | Nonsense Mutation (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- PABPC1 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PBX1 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- POLK | c.997T>C p.Y333H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRX | c.3400G>A p.V1134M | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RP1 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SHROOM4 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SLC22A24 | c.146G>T p.C49F | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SLC4A9 | c.2199C>G p.D733E (on ENST00000507527 / NM_001258428.2; = p.D709E on NM_031467.3) | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMG6 | c.1526A>G p.Y509C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAS2R3 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TCHHL1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TDRD6 | c.2683C>A p.P895T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TLN2 | c.1269A>T p.L423F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- UBE2Z | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ULK4 | c.2813C>A p.S938Y | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- UNC5C | c.1450A>C p.T484P | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNFX1 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ADGRD1 | c.1170C>T p.P390= | Silent (SNP) | VAF 110/258 reads (43%) | called by muse, mutect2, varscan2
- ATR | c.7725G>A p.A2575= | Silent (SNP) | VAF 65/238 reads (27%) | catalogued as rs587783340, COSV63385877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN14 | c.150G>A p.P50= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs746371988; called by muse, mutect2, varscan2
- DSCAML1 | c.246C>T p.G82= (on ENST00000321322; = p.G22= on NM_020693.4) | Silent (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- EEF1A2 | c.807C>T p.T269= | Silent (SNP) | VAF 98/144 reads (68%) | catalogued as rs147062680; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGF | c.3315A>G p.Q1105= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- EGR1 | c.39G>C p.P13= | Silent (SNP) | VAF 178/274 reads (65%) | called by muse, mutect2, varscan2
- FGA | c.423G>A p.L141= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- FSCN1 | c.1212G>A p.L404= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- FSTL4 | c.2217C>T p.F739= | Silent (SNP) | VAF 21/239 reads (9%) | catalogued as rs753697279, COSV54768195; called by muse, mutect2
- IGHV2-70D | c.156A>G p.G52= | Silent (SNP) | VAF 64/114 reads (56%) | called by muse, varscan2
- OR10H1 | c.270C>T p.R90= | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- OR10H2 | c.270C>T p.R90= | Silent (SNP) | VAF 31/225 reads (14%) | catalogued as COSV100008685; called by muse, mutect2, varscan2
- OR14C36 | c.462A>T p.A154= | Silent (SNP) | VAF 15/187 reads (8%) | called by muse, mutect2
- RANBP6 | c.1956C>T p.D652= | Silent (SNP) | VAF 35/405 reads (9%) | catalogued as COSV52390265; called by muse, mutect2
- RDH10 | c.246C>T p.H82= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1184286671; called by muse, mutect2, varscan2
- SREBF2 | c.1926C>T p.F642= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100761330; called by muse, mutect2, varscan2
- TMC6 | c.1059C>T p.I353= | Silent (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- TOP2B | c.849G>A p.L283= (on ENST00000264331 / NM_001330700.2; = p.L278= on NM_001068.3) | Silent (SNP) | VAF 177/369 reads (48%) | called by muse, mutect2, varscan2
- TRAM2 | c.663G>A p.Q221= | Silent (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- YAP1 | c.960G>A p.L320= (on ENST00000282441 / NM_001130145.3; = p.L282= on NM_006106.5) | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ABCG4 | chr11:119161971 A>G | 3'Flank (SNP) | VAF 205/319 reads (64%) | called by muse, mutect2, varscan2
- ADTRP | c.*48T>A | 3'UTR (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- AL353743.1 | n.373-6818A>G | Intron (SNP) | VAF 40/456 reads (9%) | catalogued as rs371242722; called by muse, mutect2
- ALDH1L1 | c.*7G>T | 3'UTR (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- ARL4A | chr7:12690921 C>A | 3'Flank (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2
- ATXN2 | c.-144C>G | 5'UTR (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- C1QTNF7 | c.-71T>A | 5'UTR (SNP) | VAF 37/283 reads (13%) | called by muse, mutect2, varscan2
- C4orf33 | c.*553T>C | 3'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs1296784421; called by muse, mutect2, varscan2
- CACNG8 | c.*5192C>A | 3'UTR (SNP) | VAF 19/262 reads (7%) | called by muse, mutect2
- CCDC88B | c.-35A>G | 5'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CHI3L1 | c.*236T>C | 3'UTR (SNP) | VAF 31/153 reads (20%) | catalogued as rs1272578831; called by muse, mutect2, varscan2
- DBF4B | c.*719C>T | 3'UTR (SNP) | VAF 45/416 reads (11%) | catalogued as rs1401502935; called by muse, mutect2, varscan2
- DCDC1 | c.4309-47A>C | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2
- DMTF1 | c.*849G>A | 3'UTR (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- EDIL3 | c.-296G>T | 5'UTR (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- EFR3A | c.*1687T>C | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- ELAC1 | c.*772G>T | 3'UTR (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- F3 | c.*649G>A | 3'UTR (SNP) | VAF 23/49 reads (47%) | catalogued as rs868555277; called by muse, mutect2, varscan2
- FAM126A | c.*465A>G | 3'UTR (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- FAM71F1 | c.809+83A>C | Intron (SNP) | VAF 32/49 reads (65%) | called by muse, mutect2, varscan2
- FANCD2 | c.*323G>T | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- FLRT2 | c.*2484G>T | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- IL18R1 | c.*102G>C | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.130-16G>A | Intron (SNP) | VAF 28/86 reads (33%) | catalogued as rs200501989; called by muse, mutect2, varscan2
- LCN8 | c.94-57C>T | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- LDB3 | c.*527G>A | 3'UTR (SNP) | VAF 84/171 reads (49%) | called by muse, varscan2
- MAP2K7 | c.*1320dup | 3'UTR (INS) | VAF 16/129 reads (12%) | catalogued as rs1306514105; called by mutect2, pindel, varscan2
- MCM6 | c.1756-12G>A | Intron (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- MPPED2 | c.*3143A>G | 3'UTR (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- NAP1L1 | c.*2656T>C | 3'UTR (SNP) | VAF 59/125 reads (47%) | called by muse, mutect2, varscan2
- NAV3 | c.*1443A>G | 3'UTR (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- NKX2-2 | c.*611C>A | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- NSMF | c.*423C>T | 3'UTR (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- PDE5A | c.*787A>C | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- PENK | chr8:56436818 ins T | 3'Flank (INS) | VAF 31/92 reads (34%) | catalogued as rs1320572848; called by mutect2, varscan2
- PGBD5 | chr1:230322947 C>T | 3'Flank (SNP) | VAF 27/314 reads (9%) | called by muse, mutect2
- PIK3C2B | c.*1132T>C | 3'UTR (SNP) | VAF 88/189 reads (47%) | called by muse, mutect2, varscan2
- PIK3CG | c.*1412C>T | 3'UTR (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- PRR5L | c.*919_*922del | 3'UTR (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel
- RAB3C | c.*3524T>A | 3'UTR (SNP) | VAF 57/157 reads (36%) | called by muse, mutect2, varscan2
- RAB5A | c.164-4967G>A | Intron (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- RAP2C-AS1 | n.722-57542C>T | Intron (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- RDX | c.1748+2359A>C | Intron (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- REEP2 | c.*1131G>A | 3'UTR (SNP) | VAF 46/73 reads (63%) | catalogued as rs1219164870; called by muse, mutect2, varscan2
- RIC3 | c.*1342G>A | 3'UTR (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- ROBO2 | c.-859C>A | 5'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- RORB | c.*708A>C | 3'UTR (SNP) | VAF 67/204 reads (33%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153421656 G>A | 3'Flank (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- SCN9A | c.*1466C>A | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- SDK1 | c.*2675G>C | 3'UTR (SNP) | VAF 15/217 reads (7%) | called by muse, mutect2
- SEC63 | c.*1605C>T | 3'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- SH3RF1 | c.*1069G>C | 3'UTR (SNP) | VAF 36/127 reads (28%) | called by muse, mutect2, varscan2
- SMAD2 | c.*8720G>C | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- SMOC2 | c.*212T>C | 3'UTR (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- SPEF1 | c.*112A>G | 3'UTR (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- SYNGR1 | c.483+1927_483+1950del | Intron (DEL) | VAF 20/122 reads (16%) | called by mutect2, pindel
- TMED9 | c.412-96A>T | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- TP63 | c.1350-5852T>G | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- TSTD2 | c.*2120A>G | 3'UTR (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- Unknown | chr21:16071169 C>T | IGR (SNP) | VAF 18/143 reads (13%) | catalogued as rs756447618; called by muse, mutect2, varscan2
- VGLL3 | c.937+5969T>C | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- WT1 | c.966-68G>T | Intron (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- ZBTB34 | c.*4343G>A | 3'UTR (SNP) | VAF 117/190 reads (62%) | called by muse, mutect2, varscan2
- ZNF518B | c.*543A>G | 3'UTR (SNP) | VAF 56/116 reads (48%) | called by muse, mutect2, varscan2
